Somatic mutation profile of tumor specimen TCGA-BP-5200-01A (aliquot TCGA-BP-5200-01A-01D-1429-08) from TCGA case TCGA-BP-5200, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G4; Age at diagnosis: 44.3 years (16,197 days).
Specimen TCGA-BP-5200-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8073ee68-8386-4065-b4eb-2791f9947df9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-5200-11A (Solid Tissue Normal), aliquot TCGA-BP-5200-11A-01D-1429-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d0822434-5f48-4e75-9a60-233de3364eaf

The open-access MAF lists 45 somatic variants for this specimen: 32 protein-altering or splice-affecting, 8 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 8, Frame Shift Del 3, Intron 2, Splice Site 1, 3'UTR 1, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA10 | c.1776G>C p.L592F | Missense Mutation (SNP) | VAF 17/227 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV52221454; called by muse, mutect2
- ADAMTS12 | c.845T>A p.F282Y | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.804); catalogued as COSV61261986; called by muse, mutect2, varscan2
- AHNAK2 | c.7285G>C p.D2429H | Missense Mutation (SNP) | VAF 128/386 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1248845948, COSV60914411; called by muse, mutect2, varscan2
- AMN | c.449T>C p.F150S | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV54486653; called by muse, mutect2, varscan2
- CAMTA2 | c.2328C>A p.F776L | Missense Mutation (SNP) | VAF 43/170 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); catalogued as COSV61834578; called by muse, mutect2, varscan2
- CENPF | c.1999A>C p.T667P | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); catalogued as COSV65274623; called by muse, mutect2, varscan2
- CNOT9 | c.634A>C p.I212L | Missense Mutation (SNP) | VAF 95/356 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV55299810; called by muse, mutect2, varscan2
- DNAAF2 | c.1325G>A p.R442K | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV53569054; called by muse, mutect2, varscan2
- DNAH9 | c.2804C>G p.P935R | Missense Mutation (SNP) | VAF 138/499 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV52331561, COSV52347321, COSV99306180; called by muse, mutect2, varscan2
- DST | c.9923C>A p.S3308Y | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.178); catalogued as COSV55011431; called by muse, mutect2, varscan2
- FBXW10 | c.2725C>A p.P909T | Missense Mutation (SNP) | VAF 46/394 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs150642944; called by muse, mutect2, varscan2
- FNIP2 | c.573G>T p.E191D | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.45); catalogued as COSV52439368; called by muse, mutect2, varscan2
- HADHA | c.950A>G p.D317G | Missense Mutation (SNP) | VAF 68/262 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV66107190; called by muse, mutect2, varscan2
- MAML2 | c.122G>A p.R41Q | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV73263317; called by muse, mutect2, varscan2
- MAP4K3 | c.367G>A p.G123R | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55712560; called by muse, mutect2, varscan2
- MCHR2 | c.541G>T p.V181F | Missense Mutation (SNP) | VAF 37/216 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.014); catalogued as COSV56002297; called by muse, mutect2, varscan2
- ODF2 | c.923T>C p.L308P (on ENST00000434106 / NM_153433.2; = p.L284P on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.648); catalogued as COSV63546816; called by muse, mutect2, varscan2
- PBRM1 | c.2153A>G p.Y718C | Missense Mutation (SNP) | VAF 125/289 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56273641; called by muse, mutect2, varscan2
- PNLIP | c.46+1G>C p.X16_splice | Splice Site (SNP) | VAF 61/196 reads (31%) | catalogued as rs772314428, COSV65040334; called by muse, mutect2, varscan2
- PPP1R9B | c.2413G>C p.E805Q | Missense Mutation (SNP) | VAF 72/277 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV57541284; called by muse, mutect2, varscan2
- RGL2 | c.2281T>C p.S761P | Missense Mutation (SNP) | VAF 38/128 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV65842241; called by muse, mutect2, varscan2
- SEMA6D | c.572T>G p.F191C | Missense Mutation (SNP) | VAF 56/150 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60376459; called by muse, mutect2, varscan2
- SEPTIN11 | c.359A>G p.Y120C | Missense Mutation (SNP) | VAF 34/224 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV53582096; called by muse, mutect2, varscan2
- SLC19A3 | c.340G>T p.G114W | Missense Mutation (SNP) | VAF 67/248 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51452526; called by muse, mutect2, varscan2
- STAM | c.1259C>T p.A420V | Missense Mutation (SNP) | VAF 31/194 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.04); catalogued as rs782156340, COSV66351411; called by muse, mutect2, varscan2
- TMCO6 | c.1244A>G p.Y415C | Missense Mutation (SNP) | VAF 52/558 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52799700; called by muse, mutect2
- TPTE2 | c.810A>C p.R270S (on ENST00000400230 / NM_199254.2; = p.R193S on NM_130785.3) | Missense Mutation (SNP) | VAF 85/303 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.619); catalogued as COSV55020402; called by muse, mutect2, varscan2
- WDR92 | c.389C>A p.P130H | Missense Mutation (SNP) | VAF 86/313 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54561287; called by muse, mutect2, varscan2
- ZFYVE16 | c.4285T>A p.C1429S | Missense Mutation (SNP) | VAF 77/159 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV62015528; called by muse, mutect2, varscan2
- MEGF6 | c.221del p.K74Rfs*104 | Frame Shift Del (DEL) | VAF 15/59 reads (25%) | called by mutect2, pindel, varscan2
- NDUFAF2 | c.41del p.S14Cfs*6 | Frame Shift Del (DEL) | VAF 6/54 reads (11%) | called by mutect2, varscan2
- RAVER2 | c.843_845delinsA p.A282Gfs*4 | Frame Shift Del (DEL) | VAF 26/237 reads (11%) | called by pindel, varscan2*
- ALDOB | c.916C>T p.L306= | Silent (SNP) | VAF 27/177 reads (15%) | catalogued as COSV100878931, COSV66397757; called by muse, mutect2, varscan2
- FCGBP | c.6921T>C p.C2307= | Silent (SNP) | VAF 34/217 reads (16%) | catalogued as rs754991159; called by muse, mutect2, varscan2
- GAGE10 | c.312G>A p.V104= | Silent (SNP) | VAF 174/272 reads (64%) | catalogued as rs1488987872, COSV68163865; called by mutect2, varscan2
- LYPD4 | c.681C>T p.S227= | Silent (SNP) | VAF 77/271 reads (28%) | catalogued as COSV58027793; called by muse, mutect2, varscan2
- OR2B11 | c.753C>T p.I251= | Silent (SNP) | VAF 36/194 reads (19%) | catalogued as rs780372908, COSV59510053; called by muse, mutect2, varscan2
- OR4E2 | c.444C>T p.L148= | Silent (SNP) | VAF 115/343 reads (34%) | catalogued as COSV57731679; called by muse, mutect2, varscan2
- PC | c.1917C>T p.F639= | Silent (SNP) | VAF 25/95 reads (26%) | catalogued as COSV67370085; called by muse, mutect2, varscan2
- VEZF1 | c.306G>A p.V102= | Silent (SNP) | VAF 90/240 reads (38%) | catalogued as COSV51968250; called by muse, mutect2, varscan2
- CDK10 | c.-2G>C | 5'UTR (SNP) | VAF 5/15 reads (33%) | catalogued as COSV58414687; called by muse, mutect2, varscan2
- NCAM1 | c.2131+2542T>C | Intron (SNP) | VAF 30/90 reads (33%) | catalogued as COSV57515580; called by muse, mutect2, varscan2
- NXF5 | n.1321A>T | RNA (SNP) | VAF 102/165 reads (62%) | catalogued as COSV53790728; called by muse, mutect2, varscan2
- PRKACB | c.47-34717C>A | Intron (SNP) | VAF 63/331 reads (19%) | catalogued as COSV65769286; called by muse, mutect2, varscan2
- PXN | c.*334T>A | 3'UTR (SNP) | VAF 34/105 reads (32%) | catalogued as COSV99935838; called by muse, mutect2, varscan2
